Somatic mutation profile of tumor specimen MP2PRT-PAUFKZ-TMP1-A (aliquot MP2PRT-PAUFKZ-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFKZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,029 days).
Specimen MP2PRT-PAUFKZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f8d193c-172a-4007-b0e0-48add61ff570.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFKZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFKZ-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebcd6a4c-dbd0-41e8-9267-a064e2640e5a

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 61/233 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CACNA1H | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 85/743 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs576035669, COSV61998368; called by muse, mutect2, varscan2
- CLCA1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146483639; called by muse, mutect2, varscan2
- CLDN10 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1419354135, COSV65300236; called by muse, mutect2, varscan2
- DPYD | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147800606, COSV64609960; called by muse, mutect2, varscan2
- IL11RA | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 149/554 reads (27%) | catalogued as rs778089627; called by muse, mutect2, varscan2
- LRRTM3 | c.1333T>A p.Y445N | Missense Mutation (SNP) | VAF 151/684 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV63663132; called by muse, mutect2, varscan2
- CD163L1 | c.3802G>A p.G1268S | Missense Mutation (SNP) | VAF 129/457 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPE | c.5876A>G p.K1959R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, varscan2
- TES | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 37/381 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRGJP1 | c.1_2insAGTA p.T2Vfs*11 | Frame Shift Ins (INS) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- CLSTN3 | c.1149C>T p.G383= | Silent (SNP) | VAF 60/383 reads (16%) | catalogued as rs761139498; called by muse, mutect2, varscan2
- IMPG2 | c.2517G>A p.S839= | Silent (SNP) | VAF 74/243 reads (30%) | catalogued as rs765258879, COSV51974448; called by muse, mutect2, varscan2
- LAMP5 | c.688C>A p.R230= | Silent (SNP) | VAF 76/257 reads (30%) | catalogued as COSV99855728; called by muse, mutect2, varscan2
- POTEC | c.255C>T p.D85= | Silent (SNP) | VAF 445/884 reads (50%) | catalogued as rs758727766, COSV62803048; called by muse, mutect2, varscan2
- PROSER2 | c.1062C>T p.S354= | Silent (SNP) | VAF 96/1100 reads (9%) | called by muse, mutect2
